Surgical pathology report (de-identified scan), TCGA case TCGA-HG-A9SC, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-HG-A9SC-01A (Primary Tumor).

[page 1 of 3]
Surg Date

SPECIMENS:

- A. LEFT PELVIC LYMPH NODES
- B. RIGHT PELVIC LYMPH NODES
- C. UTERUS, TUBES, OVARIES, AND CERVIX
- D. PARA-AORTIC NODES

SPECIMEN(S):

- A. LEFT PELVIC LYMPH NODES
- B. RIGHT PELVIC LYMPH NODES
- C. UTERUS, TUBES, OVARIES, AND CERVIX
- D. PARA-AORTIC NODES

DIAGNOSIS:

- A. LEFT PELVIC LYMPH NODES, EXCISION:
- SIX LYMPH NODES NEGATIVE FOR CARCINOMA (0/6)
- B. RIGHT PELVIC LYMPH NODES, EXCISION:
- TWELVE LYMPH NODES NEGATIVE FOR CARCINOMA (0/12)
- C. UTERUS TUBES OVARIES AND CERVIX:
- POORLY DIFFERENTIATED CERVICAL ADENOSQUAMOUS CARCINOMA, SEE COMMENT
- THE TUMOR INVADERS THE CERVICAL WALL INTO THE PARAMETRIUM
- TUMOR IS LESS THAN 0.1 MM FROM LEFT PARAMETRIAL AND ANTERIOR INKED RESECTION MARGINS
- ENDOMETRIAL POLYP
- OVARIES WITH ENDOMETRIOSIS.
- RIGHT OVARY WITH ENDOMYOMETRIOSIS
- RIGHT FALLOPIAN TUBES WITH FOCAL ENDOMETRIOSIS
- LEFT FALLOPIAN TUBE WITH CHRONIC SALPINGITIS
- LEFT OVARY WITH CYSTIC CORPUS LUTEUM
- SEE COMMENT AND SYNOPTIC REPORT
- D. PARA-AORTIC LYMPH NODES, EXCISION:
- THREE LYMPH NODES NEGATIVE FOR CARCINOMA (0/3)

COMMENT: Sections show poorly differentiated carcinoma with mainly squamous differentiation. The carcinoma cells also show occasional intracytoplasmic mucin droplets which was highlighted by mucin stain. The squamoid carcinoma cells show significant cytoplasmic clearing. The stroma shows moderate inflammatory infiltrate composed mainly of eosinophils and plasma cells. The overall findings are diagnostic of poorly differentiated adenosquamous carcinoma. Dr. has reviewed this case and he agrees with the interpretation.

SYNOPTIC REPORT - UTERINE CERVIX

Specimens Involved

- Specimens: A: LEFT PELVIC LYMPH NODES
- B: RIGHT PELVIC LYMPH NODES
- C: UTERUS, TUBES, OVARIES, AND CERVIX
- D: PARA-AORTIC NODES

Specimen Type: Hysterectomy plus bilateral salpingo-oophorectomy

Tumor Site: Circumferential

Tumor Size: Greatest dimension: 6cm

Additional dimensions: 5cm x 4cm

Other Organs Present: None

WHO CLASSIFICATION

Adenosquamous carcinoma 8560/3

Histologic Grade: G3: Poorly differentiated

Depth of Invasion: Invasion present

Depth: 2cm

Horizontal spread: 6cm

ICD-O-3

Carcinoma, adeno squamous
8560/3

Site: Cervix NOS C53.9

9/3/10/14

[page 2 of 3]
TSS**Surg Data**

Extent of Invasion: Parametrial involvement
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Present
Margins: Margins uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 0.05cm
Lymph Node Dissection: Right pelvic 0 / 12 Left pelvic 0 / 6 Para-aortic 0 / 3
Non-Lymph Node Metastases: None
Other Pathologic Findings: None identified
Pathologic Staging (pTNM [FIGO]): pT 2b N 0 M x
Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition
Distant Metastasis (pM): pMX: Cannot be assessed

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block C5
Population: Tumor Cells

Stain/Marker:Result: Comment:
MUCIN STAIN Positive Intracytoplasmic

Material: Block C8
Population: Tumor Cells

Stain/Marker:Result: Comment:
CYTOKERATIN AE1/3 Positive
CYTOKERATIN 5/6 Positive
P63 Positive
CAM 5.2 Positive
P40 Positive
P 16 Positive
MUCIN STAIN Positive

Material: Block C10
Population: Tumor Cells

Stain/Marker:Result: Comment:
MUCIN STAIN Positive

Material: Block C12
Population: Tumor Cells

Stain/Marker:Result: Comment:
MUCIN STAIN Positive

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the Immunohistochemistry Laboratory of the. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the Department of Pathology Laboratory at. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

[page 3 of 3]
TSS**Surg Date**

Special stains and/or immunohistochemical stains were performed with appropriately stained positive and/or negative controls.

GROSS DESCRIPTION:**A. LEFT PELVIC LYMPH NODES**

Received fresh labeled with patient's identification and "left pelvic lymph nodes" are multiple tan-yellow fibroadipose in aggregate 4 x 4 x 1.5 cm. Six possible lymph nodes are identified, 0.3 to 2.5 cm. The lymph nodes are submitted entirely as follows:

A1-A2, one lymph node.

A3, one bisected lymph node.

A4, three lymph nodes

A5, one bisected lymph node.

B. RIGHT PELVIC LYMPH NODES

Received fresh labeled with patient's identification and "right pelvic lymph nodes" are multiple pieces of tan-yellow fibroadipose, in aggregate 4.5 x 4 x 1 cm. Eight possible lymph nodes are identified, 0.5 to 2.4 cm. The lymph nodes are submitted entirely as follows,

B1-B3, one lymph node each.

B4, five possible lymph nodes.

B5, additional possible lymph nodes.

C. UTERUS TUBES OVARIES AND CERVIX

Received fresh labeled with patient's identification and "uterus tubes ovaries and cervix" is a 187 gm uterus with attached tubes and ovaries. The right tube is 7 cm in length x 0.4-1.3cm in diameter; the left tube is 6.8 cm in length x 0.5-1.5cm in diameter. There are adhesions identified in the left tube. The right ovary measures 3 x 1.8 x 1.2cm, with a 0.8 cm cyst filled with blood clot. The left ovary measures 3 x 1.5 x 1 cm, with a tan-yellow unremarkable cut surface. The uterus is distorted, measuring 6 x 10 x 3.5 cm, with attached cervix 4 x 3.5cm with a 1.5 cm oval os. The ectocervical mucosa is tan white and grossly unremarkable. The serosa of the uterus is smooth and unremarkable. The uterus is inked as follows: anterior blue, posterior black. The uterus is opened anterior-posteriorly to reveal a tan-white mass at endocervix, extending circumferentially around the endocervical wall, less than 1mm to the inked parametrium margin, approximately 6 x 5 x 4 cm. The endometrial cavity is distorted by the tumor, measuring 1.5 x 4.5 cm. A polypoid lesion is identified at the posterior lower endometrium, 1.8 x 1 x 0.5 cm. Another 0.8 cm polypoid lesion is identified at the anterior upper endometrium. The rest of the endometrium is unremarkable. Pictures are taken. Representative sections are submitted as follows:

C1, right tube

C2, right ovary

C3, left tube

C4, left ovary

C5-C6, 3 o'clock cervix with tumor.

C7, 6 o'clock cervix with tumor.

C8, 9 o'clock cervix with tumor.

C9, 10 o'clock cervix with tumor.

C10, 12 o'clock cervix with tumor.

C11, tumor with posterior lower uterine segment.

C12, full thickness posterior lower uterine wall with polypoid lesion.

C13, full thickness anterior uterine wall with polyp lesion.

C14, full thickness posterior uterine wall.

C15-17, anterior cervix with tumor.

D. PARA-AORTIC NODES

Received fresh labeled with patient's identification and "para-aortic nodes" are three lymph nodes, 0.6 to 1.5 cm. Entirely submitted as following:

D1, one lymph node bisected.

D2, two lymph nodes.

CLINICAL HISTORY:

None Given

Gross Dictation:, M.D., Pathologist.

Final Review:, M.D., Pathologist

Final, M.D., Pathologist,

Source: NCI Genomic Data Commons file 2631faff-5bee-45d6-b60f-30373bbdf898 (TCGA-HG-A9SC.288F7530-84F0-40F6-93F6-517DE1A481E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).